Somatic mutation profile of tumor specimen MP2PRT-PAVBTE-TMP1-A (aliquot MP2PRT-PAVBTE-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVBTE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (980 days).
Specimen MP2PRT-PAVBTE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61021d46-b881-417f-97db-6899815aa1ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVBTE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVBTE-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c9e0621-55df-47d1-93a2-e6ae44c094c3

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/263 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5930C>A p.T1977K | Missense Mutation (SNP) | VAF 66/235 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: not provided; called by muse, mutect2, varscan2
- ADAMTS14 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750319577; called by muse, mutect2
- KCNK10 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs201727669, COSV56649313; called by muse, varscan2
- PAX3 | c.1176A>G p.V392= | Splice Region (SNP) | VAF 46/187 reads (25%) | catalogued as rs1559249498; called by muse, mutect2, varscan2
- CREBBP | c.464C>G p.A155G | Missense Mutation (SNP) | VAF 124/456 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GRIA2 | c.1944G>C p.E648D | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005627 CCTCACACAGTG>ACGTTGAAAATATA | Missense Mutation (INS) | VAF 31/143 reads (22%) | called by pindel, varscan2*
- PRICKLE2 | c.525G>A p.R175= (on ENST00000295902; = p.R119= on NM_198859.4) | Silent (SNP) | VAF 62/255 reads (24%) | catalogued as rs1214972098; called by muse, mutect2, varscan2
- TNXB | c.12858T>C p.G4286= (on ENST00000647633; = p.G4039= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/442 reads (27%) | called by muse, mutect2
- TRPV1 | c.1503G>A p.P501= | Silent (SNP) | VAF 86/265 reads (32%) | catalogued as rs112906162, COSV51527209; called by muse, mutect2, varscan2
- TNS1 | c.1055-10513T>A | Intron (SNP) | VAF 49/213 reads (23%) | called by muse, mutect2, varscan2
